Gene-level copy-number profile of tumor specimen C3N-00578-04 from CPTAC case C3N-00578, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 48.8 years (17,824 days).
Specimen C3N-00578-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc9434d4-ad28-4888-a735-bcf7c96a7b48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00578-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/b7148dd9-7e9f-431f-9805-dad7fec9fb4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 168; copy number 1: 19,599; copy number 2: 33,961; copy number 3: 3,891; copy number 4: 1,274; copy number 5: 17; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 168 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,233,035–63,263,456, 4 genes: PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7.
- chr8:25,345,402–25,507,911, 5 genes (within-gene range 0–1): MIR6876, GNRH1, AC091185.1, KCTD9, CDCA2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:12,134–3,691,814, 52 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:20,331,446–26,118,408, 86 genes (broad region; genes not listed).
- chr9:41,890,314–42,668,887, 20 genes (within-gene range 0–1): CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,287,320–12,300,451, 2 genes, copy number 6: JKAMPP1, RNU2-47P.
- chr9:12,958,503–14,472,407, 17 genes, copy number 5: AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1.

Autosomal genes at a single copy (total copy number 1): 16,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
